Somatic mutation profile of tumor specimen BA2083D (aliquot aq-BA2083D) from BEATAML1.0 case 2158, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.8 years (19,276 days).
Specimen BA2083D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 622e1553-0143-4368-8c58-05739112e022.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2799D (Solid Tissue Normal), aliquot aq-BA2799D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec5df914-0d90-4719-8d5c-c9472d5ef89d

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Nonsense Mutation 2, Splice Site 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.842A>G p.D281G | Missense Mutation (SNP) | VAF 44/101 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs587781525, CM004343, CM056068, CM114008, COSV52694391, COSV52729448, COSV52815868; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANK1 | c.3965G>A p.R1322H | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs374960063; called by muse, mutect2, varscan2
- DICER1 | c.5126A>G p.D1709G | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555366979, COSV58615493, COSV58625198; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSP | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs377749481, CM1314713; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FKBP3 | c.98del p.G33Vfs*12 | Frame Shift Del (DEL) | VAF 23/66 reads (35%) | catalogued as rs1013264249; called by mutect2, pindel, varscan2
- PSAP | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs747485660, COSV56451607; called by muse, mutect2, varscan2
- AFDN | c.740G>C p.G247A | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ATP10A | c.4085G>A p.C1362Y | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- C1orf158 | c.383A>T p.K128M | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- COL12A1 | c.2164+1G>T p.X722_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- FAM20A | c.803A>G p.H268R | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- FOXD2 | c.1024G>T p.G342C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- KCND3 | c.1030A>T p.K344* | Nonsense Mutation (SNP) | VAF 45/126 reads (36%) | called by muse, mutect2, varscan2
- NCKAP5 | c.1693C>A p.P565T | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- POLR1F | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- RASEF | c.1647C>G p.D549E | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- ZNF300 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- CFAP52 | c.1860C>A p.S620= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- DSCAML1 | c.1593C>T p.N531= (on ENST00000321322; = p.N471= on NM_020693.4) | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs146015983, COSV100356237; called by mutect2, varscan2
- HSD17B3 | c.189G>A p.A63= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as rs372189709; called by mutect2, varscan2
- NODAL | c.108G>T p.S36= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- PRRT4 | c.1161C>G p.L387= | Silent (SNP) | VAF 8/31 reads (26%) | called by mutect2, varscan2
- ZBTB24 | c.1353C>T p.T451= | Silent (SNP) | VAF 43/171 reads (25%) | called by muse, mutect2, varscan2
- OR2A13P | n.856C>A | RNA (SNP) | VAF 9/84 reads (11%) | catalogued as rs751393761; called by mutect2, varscan2
